MMRF case MMRF_2514 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/e3bef2b4-bb08-480c-9a42-7ca1fe436469

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.3 years (23,138 days); ISS stage: I; Days to last known disease status: 651 days (1.8 years); Days to last follow up: 651 days (1.8 years).
   Treatment given: Therapeutic agents: Bortezomib + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 23 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 24 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 105 days; Days to treatment end: 210 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 105 days; Days to treatment end: 196 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 287 days; Days to treatment end: 389 days (1.1 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 418 days (1.1 years); Days to treatment end: 418 days (1.1 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 420 days (1.1 years); Days to treatment end: 420 days (1.1 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 555 days (1.5 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -3 (ECOG 1): M Protein 3.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.5 mg/dL; Immunoglobulin G 39.9 g/L; Immunoglobulin A 1.11 g/L; Immunoglobulin M 0.213 g/L; Beta 2 Microglobulin 2.1 µg/mL; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 14.1 ×10⁹/L; Absolute Neutrophil 11.9 ×10⁹/L; Platelets 310 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.43 mmol/L; Albumin 36 g/L; Total Protein 9.2 g/dL; Glucose 5.83 mmol/L.
- Day 94: M Protein 0.9 g/dL; Immunoglobulin G 16 g/L; Hemoglobin 7.38 mmol/L; Absolute Neutrophil 8.3 ×10⁹/L; Platelets 424 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L; Albumin 35 g/L; Total Protein 7.3 g/dL; Glucose 6.38 mmol/L.
- Day 196: M Protein 0.4 g/dL; Lactate Dehydrogenase 6.53 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 5.7 ×10⁹/L; Platelets 234 ×10⁹/L.
- Day 277 (ECOG 1): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.1 mg/dL; Immunoglobulin G 13.2 g/L; Immunoglobulin A 1.69 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 268 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 7.3 g/dL; Glucose 7.15 mmol/L.
- Day 343: Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 317 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.55 mmol/L; Albumin 45 g/L; Total Protein 7.8 g/dL; Glucose 5.17 mmol/L.
- Day 449 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.2 mg/dL; Immunoglobulin G 7.53 g/L; Immunoglobulin A 1.94 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 3.6 µg/mL; Lactate Dehydrogenase 3.52 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 8.7 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 259 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 6.27 mmol/L.
- Day 526 (ECOG 1): M Protein 0.3 g/dL; Immunoglobulin G 6.63 g/L; Immunoglobulin A 1.49 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 9.2 ×10⁹/L; Absolute Neutrophil 7 ×10⁹/L; Platelets 267 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.58 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 6.27 mmol/L.
- Day 651: M Protein 0.2 g/dL; Immunoglobulin G 8.17 g/L; Immunoglobulin A 2.59 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 7.33 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 241 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.6 mmol/L; Albumin 37 g/L; Total Protein 6.2 g/dL; Glucose 5.28 mmol/L.

Other clinical attributes
- Day -3: Weight: 71 kg; Height: 167 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2514_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -3 days.
- Sample MMRF_2514_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -3 days.
